Somatic mutation profile of tumor specimen MMRF_1309_2_BM_CD138pos (aliquot MMRF_1309_2_BM_CD138pos_T1_KHS5U_L12901) from MMRF case MMRF_1309, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.7 years (30,580 days).
Specimen MMRF_1309_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14f923f2-b55c-40f9-ad76-9745a1e7efad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1309_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1309_1_PB_Whole_C3_KBS5U_L02860; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d4e6b61-2755-419b-bc21-8a4d14d29c03

The open-access MAF lists 143 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 36, Silent 20, Intron 17, 5'Flank 5, 5'UTR 2, RNA 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 34/570 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACBD4 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs747689259; called by muse, mutect2, varscan2
- ADAMTS16 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs758166784, COSV56995114; called by muse, mutect2, varscan2
- ARFGEF3 | c.3464C>T p.S1155F | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99292222; called by muse, mutect2, varscan2
- BMPR2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV101001402; called by muse, mutect2
- BRINP3 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 91/275 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV66527581; called by muse, mutect2, varscan2
- COL6A1 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs753485651, COSV62612049; called by muse, mutect2, varscan2
- CSMD3 | c.5872C>A p.P1958T (on ENST00000297405 / NM_001363185.1; = p.P1854T on NM_052900.3) | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1315799375; called by muse, mutect2
- DPYSL3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs781130845, COSV58327316; called by muse, mutect2
- DSP | c.7193A>G p.N2398S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1251606363; called by muse, mutect2, varscan2
- FARS2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375460524, COSV51172566, COSV51176224; called by muse, mutect2, varscan2
- GPC5 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs868574650; called by muse, mutect2
- GSX1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as rs1056283090; called by muse, mutect2
- HOXB4 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.548); catalogued as COSV60177922; called by muse, mutect2, varscan2
- IGLV2-8 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs11558646; called by muse, mutect2, varscan2
- IGLV3-25 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as rs1224954062; called by muse, varscan2
- IPO13 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs770488466; called by muse, varscan2
- IQGAP3 | c.4411C>T p.R1471C | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs748938834, COSV100752483; called by muse, mutect2, varscan2
- MFAP3L | c.343del p.V115Yfs*20 | Frame Shift Del (DEL) | VAF 70/248 reads (28%) | catalogued as COSV64371813; called by mutect2, pindel*, varscan2
- MYO10 | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 116/389 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs775296512; called by muse, mutect2, varscan2
- NKTR | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.523); catalogued as rs937651215; called by muse, mutect2, varscan2
- OSBPL1A | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1197146685; called by muse, mutect2
- OTOF | c.4991C>T p.A1664V (on ENST00000272371 / NM_194248.3; = p.A897V on NM_004802.4) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1410079943, COSV55519537, COSV99718187; called by muse, mutect2, varscan2
- PA2G4 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); catalogued as COSV57262158; called by muse, mutect2
- PCDHA13 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as rs782045843, COSV56519550; called by muse, mutect2, varscan2
- PPP1R13L | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779760960, COSV100714662; called by muse, mutect2, varscan2
- ROBO1 | c.2578T>G p.S860A | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs765830793; called by muse, mutect2, varscan2
- SBF1 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100818126; called by muse, mutect2, varscan2
- SUSD2 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778152993; called by muse, mutect2, varscan2
- TTC33 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs751422389, COSV61802488; called by muse, mutect2, varscan2
- WDR64 | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750575442; called by muse, mutect2, varscan2
- AMOTL2 | c.1716G>T p.K572N | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BUB1 | c.3216G>C p.R1072S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC73 | c.657dup p.A220Sfs*15 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- CHD6 | c.6972G>T p.L2324F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.17); called by muse, mutect2
- CNOT3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CORO1A | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DLD | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- ECT2 | c.1414G>C p.A472P (on ENST00000392692 / NM_001349098.2; = p.A441P on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.334); called by muse, mutect2
- EDEM1 | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- FAM210B | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 101/209 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDF9 | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- HIVEP3 | c.4282A>G p.S1428G | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- HNRNPAB | c.448_450del p.K150del | In Frame Del (DEL) | VAF 22/99 reads (22%) | called by pindel, varscan2
- IGKV2-24 | chr2:89176326 del TGAGGA | Missense Mutation (DEL) | VAF 35/43 reads (81%) | called by mutect2, pindel, varscan2
- KLHL38 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PAN3 | c.1498T>A p.F500I | Missense Mutation (SNP) | VAF 117/266 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTPRN2 | c.1739A>T p.K580I | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2
- RILPL2 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SDK2 | c.4478C>T p.S1493L | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAPT1 | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- THSD7B | c.3958G>T p.D1320Y (on ENST00000272643; = p.D1318Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TTN | c.71822C>T p.T23941I (on ENST00000591111; = p.T16517I on NM_003319.4) | Missense Mutation (SNP) | VAF 105/224 reads (47%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13D | c.952T>A p.W318R | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIK1 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZNF107 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF17 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF276 | c.1006+1G>A p.X336_splice (on ENST00000443381 / NM_001113525.2; = p.X261_splice on NM_152287.4) | Splice Site (SNP) | VAF 29/31 reads (94%) | called by muse, mutect2, varscan2
- ZNF529 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- ZNF563 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF653 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, varscan2
- ABCC8 | c.1791C>T p.V597= | Silent (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- ARID5B | c.175C>T p.L59= | Silent (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- AZGP1 | c.564G>A p.A188= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs375811707; called by muse, mutect2, varscan2
- B3GAT1 | c.612C>G p.L204= | Silent (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- CACNG6 | c.163C>T p.L55= | Silent (SNP) | VAF 33/114 reads (29%) | called by muse, mutect2, varscan2
- CLPS | c.78C>T p.I26= | Silent (SNP) | VAF 56/240 reads (23%) | catalogued as rs1482413707; called by muse, mutect2, varscan2
- EPB41L2 | c.604C>T p.L202= | Silent (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- FZD7 | c.363T>C p.R121= | Silent (SNP) | VAF 58/109 reads (53%) | called by muse, mutect2, varscan2
- IFITM1 | c.378G>A p.*126= | Silent (SNP) | VAF 49/127 reads (39%) | called by muse, mutect2, varscan2
- IGFL1 | c.285C>T p.C95= | Silent (SNP) | VAF 112/329 reads (34%) | catalogued as rs370059487; called by muse, mutect2, varscan2
- IGLL5 | c.135G>A p.P45= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as rs766249945, COSV104440294, COSV73250373; called by muse, varscan2
- MAP3K14 | c.159A>T p.G53= | Silent (SNP) | VAF 73/260 reads (28%) | catalogued as COSV60923851; called by muse, varscan2
- PCDHGA1 | c.2289G>A p.S763= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV65296482; called by muse, mutect2, varscan2
- PDGFC | c.735A>G p.V245= | Silent (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- PITPNM1 | c.2079C>T p.F693= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV62709371; called by muse, mutect2, varscan2
- PRKAG3 | c.510G>T p.L170= | Silent (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2, varscan2
- PRR23B | c.354G>A p.S118= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as COSV61493585; called by muse, mutect2, varscan2
- SHISA7 | c.1212C>T p.R404= | Silent (SNP) | VAF 38/149 reads (26%) | called by muse, mutect2, varscan2
- ZNF385A | c.549G>A p.P183= (on ENST00000338010 / NM_001130967.3; = p.P163= on NM_015481.3) | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs779071587; called by muse, mutect2, varscan2
- ZNF536 | c.1482C>A p.L494= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV62817673, COSV62834139; called by muse, mutect2, varscan2
- AMOTL1 | c.*2991_*2992insGCAC | 3'UTR (INS) | VAF 4/32 reads (13%) | catalogued as rs748632392; called by pindel, varscan2
- ARHGAP42 | c.*243G>C | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- ATAD2B | c.*1894dup | 3'UTR (INS) | VAF 41/89 reads (46%) | called by mutect2, pindel, varscan2
- ATRX | c.*479A>G | 3'UTR (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021268 C>T | 5'Flank (SNP) | VAF 67/130 reads (52%) | catalogued as rs913987622, COSV55850778; called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>T | 5'Flank (SNP) | VAF 65/131 reads (50%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- C2CD3 | c.5881+1065T>G | Intron (SNP) | VAF 100/211 reads (47%) | called by muse, mutect2, varscan2
- CCDC198 | c.*1563G>A | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- CEMIP | c.*2362G>A | 3'UTR (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- CILK1 | c.*456A>T | 3'UTR (SNP) | VAF 58/117 reads (50%) | called by muse, mutect2, varscan2
- COL16A1 | c.3195+18C>T | Intron (SNP) | VAF 66/117 reads (56%) | catalogued as rs1304456716; called by muse, mutect2, varscan2
- CREB5 | c.*5760G>A | 3'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- CYP4F24P | n.791C>T | RNA (SNP) | VAF 111/431 reads (26%) | catalogued as rs547682452; called by muse, mutect2, varscan2
- DACH2 | c.1751-811G>A | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- DOK4 | c.*861del | 3'UTR (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel*, varscan2
- DOT1L | c.4606+1244G>A | Intron (SNP) | VAF 92/378 reads (24%) | catalogued as rs1323581161; called by muse, mutect2, varscan2
- E2F7 | c.*931A>C | 3'UTR (SNP) | VAF 52/129 reads (40%) | called by muse, mutect2, varscan2
- ECSIT | c.*2C>G | 3'UTR (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- ETV1 | c.181+402G>T | Intron (SNP) | VAF 402/639 reads (63%) | called by muse, mutect2, varscan2
- FAM217A | c.-87C>T | 5'UTR (SNP) | VAF 23/45 reads (51%) | catalogued as rs527874806; called by muse, mutect2, varscan2
- GLI3 | c.*1496C>T | 3'UTR (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- GLRX2 | chr1:193105915 C>T | 5'Flank (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- GPT2 | c.*1024C>T | 3'UTR (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1085-39G>T | Intron (SNP) | VAF 93/196 reads (47%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.-12T>C | 5'UTR (SNP) | VAF 48/133 reads (36%) | catalogued as rs1555541674; called by muse, mutect2, varscan2
- KIAA0586 | c.4450+3751G>T | Intron (SNP) | VAF 64/139 reads (46%) | called by muse, mutect2
- LILRB5 | c.1475-122C>T | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs548100118; called by muse, mutect2, varscan2
- LNX1 | c.*245dup | 3'UTR (INS) | VAF 19/82 reads (23%) | catalogued as rs1182549777; called by mutect2, pindel, varscan2
- LRP12 | c.*100del | 3'UTR (DEL) | VAF 38/108 reads (35%) | catalogued as rs1564127019; called by mutect2, pindel, varscan2
- LRRC58 | c.*3655G>A | 3'UTR (SNP) | VAF 7/20 reads (35%) | catalogued as rs1288970257; called by muse, mutect2, varscan2
- MBP | c.576+1001A>G | Intron (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- MIR487B | n.36G>A | RNA (SNP) | VAF 8/56 reads (14%) | catalogued as rs764936726; called by muse, mutect2, varscan2
- NFU1 | chr2:69437563 G>A | 5'Flank (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- NLRP12 | chr19:53824386 C>A | 5'Flank (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- OSCAR | c.*949C>T | 3'UTR (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- PARVB | c.712+235C>G | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- PAX5 | c.*1002C>T | 3'UTR (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- PCSK6 | c.*298C>A | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- PDGFC | c.*748G>T | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*5095T>C | 3'UTR (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- PNP | c.461+36G>A | Intron (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- PRKRA | c.785-120G>T | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- PSMC1 | c.279+21_279+23del | Intron (DEL) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- RPE65 | c.*11G>A | 3'UTR (SNP) | VAF 94/345 reads (27%) | called by muse, mutect2, varscan2
- RPS15A | c.*61C>T | 3'UTR (SNP) | VAF 17/239 reads (7%) | catalogued as rs904945052; called by muse, mutect2
- S1PR2 | c.-43+743C>G | Intron (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- SCX | c.*193G>A | 3'UTR (SNP) | VAF 23/64 reads (36%) | catalogued as rs894149596; called by muse, mutect2, varscan2
- SERPINA1 | c.*920A>G | 3'UTR (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2
- SH3TC2 | c.279+96G>C | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2
- SLC6A14 | c.*105G>A | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*2519C>T | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*3026T>C | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- SSR1 | c.*486G>A | 3'UTR (SNP) | VAF 48/212 reads (23%) | catalogued as rs1000794351; called by muse, mutect2, varscan2
- TIMP3 | c.*411T>C | 3'UTR (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- TMEFF2 | c.*626G>T | 3'UTR (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- TMEM182 | c.*1950G>T | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- TNKS | c.673+1582A>T | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- TP53INP1 | c.*945C>T | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- USP49 | c.*1989dup | 3'UTR (INS) | VAF 17/47 reads (36%) | catalogued as rs1225821586; called by mutect2, varscan2
- VGLL3 | c.*2805A>G | 3'UTR (SNP) | VAF 17/48 reads (35%) | catalogued as rs1447622658; called by muse, mutect2, varscan2
- WNT4 | c.313+2536C>T | Intron (SNP) | VAF 21/47 reads (45%) | catalogued as rs543244998; called by muse, mutect2, varscan2
- XRCC2 | c.*1497G>A | 3'UTR (SNP) | VAF 7/158 reads (4%) | called by muse, mutect2
